Gene-level copy-number profile of tumor specimen TCGA-A2-A0EY-01A from TCGA case TCGA-A2-A0EY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,872 days).
Specimen TCGA-A2-A0EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.93f09df2-f3c1-43d6-9c79-4751740bfa45.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0EY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2e526e2-66f8-429b-93a5-156b05368940

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 867; copy number 2: 15,991; copy number 3: 17,147; copy number 4: 13,952; copy number 5: 8,631; copy number 6: 2,687; copy number 7: 60; copy number 8: 83; copy number 9: 61; copy number 10: 37; copy number 11: 101; copy number 13: 54; copy number 14: 34; copy number 18: 12; copy number 25: 4; copy number 27: 11; copy number 29: 20; copy number 37: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0EY-01A-11D-A036-01): tumor purity 0.51, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 454 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,132,350–192,185,815, 21 genes, copy number 7: GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18.
- chr1:192,246,708–192,367,285, 3 genes, copy number 7: AL513175.1, AL513175.2, RGS21.
- chr2:168,771,951–168,913,371, 4 genes, copy number 9: CERS6-AS1, NOSTRIN, SPC25, G6PC2.
- chr3:173,396,284–174,378,005, 6 genes, copy number 7 (within-gene range 5–7): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr6:70,856,679–70,957,060, 1 gene, copy number 8: B3GAT2.
- chr6:73,693,903–74,004,812, 4 genes, copy number 8: AL590428.1, CD109, AL590552.1, TXNP7.
- chr9:26,642,697–31,166,980, 47 genes, copy number 8–10: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1.
- chr14:21,841,240–22,482,959, 57 genes, copy number 9 (within-gene range 5–9): TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:41,514,972–41,904,549, 6 genes, copy number 10 (within-gene range 6–10): AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1.
- chr14:49,373,966–51,825,422, 89 genes, copy number 7–13 (broad region; genes not listed).
- chr16:68,189,287–68,477,570, 25 genes, copy number 10–14: AC130462.1, AC020978.6, AC020978.8, RPS12P27, AC020978.3, AC020978.7, AC020978.5, ESRP2, MIR6773, AC020978.4, PLA2G15, AC020978.2, SLC7A6, RNU6-1262P, SLC7A6OS, AC020978.9, PRMT7, AC020978.1, RNU4-30P, SMPD3, AC099521.2, AC099521.3, AC099521.1, Y_RNA, RPL35AP33.
- chr17:20,008,865–20,319,026, 1 gene, copy number 18 (within-gene range 3–18): SPECC1.
- chr17:20,111,824–21,783,465, 87 genes, copy number 10–37 (broad region; genes not listed).
- chr17:39,057,019–39,864,312, 28 genes, copy number 18–29 (within-gene range 2–29): RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:41,377,650–41,397,608, 2 genes, copy number 8: KRT34, KRT31.
- chr17:49,202,791–49,318,011, 4 genes, copy number 25 (within-gene range 3–25): GNGT2, ABI3, PHOSPHO1, FLJ40194.
- chr17:66,267,743–67,366,605, 24 genes, copy number 7–27: RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12.
- chr17:67,408,774–67,408,881, 1 gene, copy number 7: Y_RNA.
- chr17:82,942,155–83,051,810, 1 gene, copy number 7 (within-gene range 3–7): B3GNTL1.
- chr17:83,079,609–83,095,122, 1 gene, copy number 7: METRNL.
- chr19:9,363,020–9,539,734, 10 genes, copy number 8 (within-gene range 6–8): ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT.
- chr22:16,690,103–17,165,445, 31 genes, copy number 11 (within-gene range 6–11): VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1.
- chr22:17,192,936–17,193,308, 1 gene, copy number 11: AC005300.1.

Autosomal genes at a single copy (total copy number 1): 867. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
